Somatic mutation profile of tumor specimen 0DPHAT from CCDI case PBCDNA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,128 days).
Specimen 0DPHAT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9909d80f-cf57-4b32-91c0-e669ecfc1b77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPHA0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93634e5d-32ae-4e77-be72-dea02c90e351

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIP2A | c.1213A>T p.N405Y | Missense Mutation (SNP) | VAF 107/494 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DPP6 | c.2327T>A p.V776D (on ENST00000377770 / NM_001364500.2; = p.V714D on NM_001936.5) | Missense Mutation (SNP) | VAF 120/461 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NF2 | c.80_100del p.V27_M33del | In Frame Del (DEL) | VAF 41/212 reads (19%) | called by mutect2, pindel, varscan2
- TTN | c.27413C>T p.T9138I (on ENST00000591111; = p.T8211I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/447 reads (24%) | PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ATAD5 | c.5031T>C p.F1677= | Silent (SNP) | VAF 181/942 reads (19%) | catalogued as rs1301738249; called by muse, mutect2, varscan2
